Somatic mutation profile of cancer-model specimen HCM-SANG-0299-C15-85X (3D Organoid; aliquot HCM-SANG-0299-C15-85X-01D-A78U-36), derived from the primary tumor of HCMI case HCM-SANG-0299-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS.
Specimen HCM-SANG-0299-C15-85X: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0f9e62c0-27c2-48da-a59a-7692273278c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0299-C15-10B (Blood Derived Normal), aliquot HCM-SANG-0299-C15-10B-01D-A78U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/593f1288-e6b1-44f9-a784-4c0e0397f3c5

The open-access MAF lists 143 somatic variants for this specimen: 97 protein-altering or splice-affecting, 32 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 82, Silent 32, Nonsense Mutation 6, Intron 4, Frame Shift Del 3, 3'Flank 3, RNA 2, 3'UTR 2, 5'Flank 2, Splice Region 2, Splice Site 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 189/189 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ALMS1 | c.9824A>G p.K3275R | Missense Mutation (SNP) | VAF 85/294 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.469); catalogued as rs1190838515; called by muse, mutect2, varscan2
- APOL3 | c.887G>A p.R296H (on ENST00000349314 / NM_145640.2; = p.R225H on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/191 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.046); catalogued as rs757180712; called by muse, mutect2, varscan2
- CCDC136 | c.1606-5C>T | Splice Region (SNP) | VAF 104/158 reads (66%) | catalogued as rs905348863; called by muse, mutect2, varscan2
- CCDC63 | c.1006C>T p.R336W | Missense Mutation (SNP) | VAF 90/356 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.736); catalogued as rs369178253; called by muse, mutect2, varscan2
- CCNB3 | c.1883C>G p.S628C | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); catalogued as COSV52071169; called by muse, mutect2, varscan2
- CERS6 | c.394T>G p.F132V | Missense Mutation (SNP) | VAF 8/214 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59830623; called by muse, mutect2
- CFAP54 | c.7399G>T p.G2467* | Nonsense Mutation (SNP) | VAF 74/111 reads (67%) | catalogued as COSV61574271; called by muse, mutect2, varscan2
- CHRM2 | c.506G>T p.R169I | Missense Mutation (SNP) | VAF 105/273 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57769105; called by muse, mutect2, varscan2
- CNTNAP5 | c.872A>G p.H291R | Missense Mutation (SNP) | VAF 47/159 reads (30%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); catalogued as rs755973563; called by muse, mutect2, varscan2
- CRAMP1 | c.1522G>A p.A508T | Missense Mutation (SNP) | VAF 101/102 reads (99%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.007); catalogued as rs754112928; called by muse, mutect2, varscan2
- DACH1 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 103/148 reads (70%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); catalogued as COSV57516881; called by muse, mutect2, varscan2
- GBF1 | c.4063G>A p.V1355I (on ENST00000369983 / NM_001377137.1; = p.V1354I on NM_004193.3) | Missense Mutation (SNP) | VAF 56/105 reads (53%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs141610784; called by muse, mutect2, varscan2
- GPAA1 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 169/391 reads (43%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.643); catalogued as rs782374867; called by muse, mutect2, varscan2
- GRID2 | c.1099C>T p.R367C | Missense Mutation (SNP) | VAF 73/218 reads (33%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.765); catalogued as rs544360335, COSV99948558; called by muse, mutect2, varscan2
- GRM5 | c.1570C>T p.R524* | Nonsense Mutation (SNP) | VAF 83/170 reads (49%) | catalogued as rs1259002284, COSV59616743; called by muse, mutect2, varscan2
- KAT2B | c.1583G>A p.R528Q | Missense Mutation (SNP) | VAF 185/196 reads (94%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as rs1205273470, COSV55434569; called by muse, mutect2, varscan2
- KIR3DL3 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 132/274 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs1277875430, COSV52550084; called by muse, mutect2, varscan2
- LHFPL5 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 20/453 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1338945107, COSV64177159; called by muse, mutect2
- LNPEP | c.435C>A p.N145K | Missense Mutation (SNP) | VAF 77/184 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs758200052, COSV51481596; called by muse, mutect2, varscan2
- MRC2 | c.4129G>A p.G1377R | Missense Mutation (SNP) | VAF 147/224 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200529475; called by muse, mutect2, varscan2
- MTR | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 86/383 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs376681897; called by muse, mutect2, varscan2
- MYLK4 | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 74/136 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as rs757508603, COSV99193684; called by muse, mutect2
- NBEA | c.1730T>C p.F577S | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV59814694; called by muse, mutect2, varscan2
- NUP210 | c.380A>C p.E127A | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54409669; called by muse, mutect2, varscan2
- PDE1C | c.1460G>C p.G487A | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.699); catalogued as COSV58503226; called by muse, mutect2, varscan2
- PDZRN4 | c.1585-2A>G p.X529_splice (on ENST00000402685 / NM_001164595.2; = p.X271_splice on NM_013377.4) | Splice Site (SNP) | VAF 24/97 reads (25%) | catalogued as rs1281243488; called by muse, mutect2, varscan2
- PPP1R12C | c.1432A>G p.K478E | Missense Mutation (SNP) | VAF 13/301 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.428); catalogued as rs1173984819; called by muse, mutect2
- PREX2 | c.141G>A p.S47= | Splice Region (SNP) | VAF 223/609 reads (37%) | catalogued as COSV55800780; called by muse, mutect2, varscan2
- RGS12 | c.1433C>T p.P478L | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.66); PolyPhen benign (0.028); catalogued as rs545165653, COSV60902115; called by muse, mutect2, varscan2
- RIMBP2 | c.983C>T p.T328M | Missense Mutation (SNP) | VAF 110/336 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs370841973; called by muse, mutect2, varscan2
- SHISA7 | c.969G>T p.K323N | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV66244503; called by muse, mutect2, varscan2
- SLC25A47 | c.31G>A p.V11I | Missense Mutation (SNP) | VAF 51/196 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs574817448, COSV64162073; called by muse, mutect2, varscan2
- SMCHD1 | c.2288C>T p.S763L | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV55250956, COSV55263008; called by muse, mutect2
- SPTBN5 | c.4816G>A p.G1606S | Missense Mutation (SNP) | VAF 203/420 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.266); catalogued as rs1456048646; called by muse, mutect2, varscan2
- TRIM51 | c.503G>A p.W168* | Nonsense Mutation (SNP) | VAF 7/158 reads (4%) | catalogued as COSV55265463; called by muse, mutect2
- UMODL1 | c.1133C>G p.T378S | Missense Mutation (SNP) | VAF 65/171 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.229); catalogued as rs1479607186; called by muse, mutect2, varscan2
- ZNF300 | c.104A>T p.D35V | Missense Mutation (SNP) | VAF 58/119 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs764933049; called by muse, mutect2, varscan2
- ZNF572 | c.1175G>C p.S392T | Missense Mutation (SNP) | VAF 50/310 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100073855, COSV60001228; called by muse, mutect2, varscan2
- ZNF681 | c.1393C>A p.L465I | Missense Mutation (SNP) | VAF 11/229 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV68074511; called by muse, mutect2
- ADAMTS17 | c.421C>T p.L141F | Missense Mutation (SNP) | VAF 270/270 reads (100%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- ARHGEF7 | c.2214C>A p.D738E (on ENST00000375741 / NM_001113511.2; = p.D717E on NM_145735.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/186 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ARID1A | c.266_269del p.G89Afs*11 | Frame Shift Del (DEL) | VAF 16/37 reads (43%) | called by mutect2, pindel, varscan2
- BGN | c.239-1G>A p.X80_splice | Splice Site (SNP) | VAF 38/38 reads (100%) | called by muse, mutect2
- BIRC6 | c.8545G>T p.E2849* | Nonsense Mutation (SNP) | VAF 65/108 reads (60%) | called by muse, mutect2, varscan2
- C12orf42 | c.154C>A p.P52T | Missense Mutation (SNP) | VAF 59/94 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- CABS1 | c.1021G>T p.E341* | Nonsense Mutation (SNP) | VAF 49/129 reads (38%) | called by muse, mutect2, varscan2
- CDH20 | c.100T>G p.S34A | Missense Mutation (SNP) | VAF 81/225 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CEP112 | c.1831G>A p.E611K | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CLCN7 | c.55G>C p.E19Q | Missense Mutation (SNP) | VAF 7/192 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.051); called by muse, mutect2
- COL9A2 | c.908del p.P303Qfs*15 | Frame Shift Del (DEL) | VAF 70/369 reads (19%) | called by mutect2, pindel, varscan2
- CTCFL | c.395A>G p.Q132R | Missense Mutation (SNP) | VAF 126/605 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM13C | c.103G>T p.D35Y | Missense Mutation (SNP) | VAF 71/185 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- FBXO38 | c.3110C>T p.P1037L (on ENST00000340253 / NM_205836.3; = p.P962L on NM_030793.5) | Missense Mutation (SNP) | VAF 70/150 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- FLG | c.1787A>G p.D596G | Missense Mutation (SNP) | VAF 28/904 reads (3%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.705); called by muse, mutect2
- GBP4 | c.710A>C p.E237A | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- KIF26A | c.2336_2337dup p.S780Tfs*43 | Frame Shift Ins (INS) | VAF 96/317 reads (30%) | called by mutect2, pindel, varscan2
- LRRC42 | c.594del p.A199Pfs*5 | Frame Shift Del (DEL) | VAF 31/204 reads (15%) | called by mutect2, pindel, varscan2
- MAST1 | c.2473C>G p.P825A | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MCM9 | c.2470G>C p.A824P | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.047); called by muse, mutect2
- MS4A8 | c.643A>C p.S215R | Missense Mutation (SNP) | VAF 160/303 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- NBPF1 | c.1853A>G p.Q618R | Missense Mutation (SNP) | VAF 55/623 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- NEDD9 | c.62A>T p.E21V | Missense Mutation (SNP) | VAF 64/155 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR10A7 | c.599T>G p.L200R | Missense Mutation (SNP) | VAF 132/396 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- OSGIN2 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- PCDHA2 | c.227A>G p.E76G | Missense Mutation (SNP) | VAF 198/770 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.203); called by muse, mutect2
- PCDHA2 | c.229G>T p.V77L | Missense Mutation (SNP) | VAF 199/774 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.195); called by muse, mutect2
- PDCL2 | c.618G>T p.L206F | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PDZRN4 | c.105C>G p.H35Q | Missense Mutation (SNP) | VAF 306/619 reads (49%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- PLSCR5 | c.366G>T p.R122S | Missense Mutation (SNP) | VAF 144/337 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- POU3F1 | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 97/332 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.198); called by muse, varscan2
- PPFIA4 | c.323G>T p.R108L | Missense Mutation (SNP) | VAF 56/227 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- PPFIA4 | c.2399G>A p.G800E (on ENST00000447715; = p.G801E on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/408 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- PTPRJ | c.1187A>C p.N396T | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.044); called by muse, mutect2
- RAB3GAP1 | c.164C>G p.S55C | Missense Mutation (SNP) | VAF 52/180 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- REG3G | c.15G>A p.M5I | Missense Mutation (SNP) | VAF 53/188 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- REXO4 | c.646G>C p.A216P | Missense Mutation (SNP) | VAF 90/348 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- RTL9 | c.1306G>A p.A436T | Missense Mutation (SNP) | VAF 156/156 reads (100%) | SIFT tolerated (0.27); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- SERPINB2 | c.226T>C p.F76L | Missense Mutation (SNP) | VAF 53/160 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SIK2 | c.2365C>G p.P789A | Missense Mutation (SNP) | VAF 89/202 reads (44%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SIPA1L1 | c.1994C>T p.T665I | Missense Mutation (SNP) | VAF 93/146 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- SLC4A8 | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 47/159 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLCO1B1 | c.76G>T p.G26* | Nonsense Mutation (SNP) | VAF 104/104 reads (100%) | called by muse, mutect2, varscan2
- SLCO5A1 | c.415_417del p.F139del | In Frame Del (DEL) | VAF 100/490 reads (20%) | called by mutect2, pindel, varscan2
- SMG9 | c.833T>G p.I278S | Missense Mutation (SNP) | VAF 90/210 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- SOHLH1 | c.17C>T p.S6F | Missense Mutation (SNP) | VAF 124/523 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SYNE1 | c.1889A>G p.E630G (on ENST00000367255 / NM_182961.4; = p.E637G on NM_033071.3) | Missense Mutation (SNP) | VAF 12/328 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TBC1D14 | c.1369G>A p.A457T | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- TNN | c.3122T>C p.L1041P | Missense Mutation (SNP) | VAF 45/181 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TTC21A | c.3827T>G p.L1276R | Missense Mutation (SNP) | VAF 84/206 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UBQLNL | c.292T>G p.L98V | Missense Mutation (SNP) | VAF 62/189 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- UNC79 | c.4331C>T p.A1444V (on ENST00000393151 / NM_001346218.2; = p.A1267V on NM_020818.5) | Missense Mutation (SNP) | VAF 60/228 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- USP34 | c.1617G>A p.M539I | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- UTRN | c.6265T>G p.Y2089D | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- ZNF19 | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 105/106 reads (99%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF223 | c.577A>G p.I193V | Missense Mutation (SNP) | VAF 56/202 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.015); called by muse, mutect2
- ZNF234 | c.1897T>G p.F633V | Missense Mutation (SNP) | VAF 70/210 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCB5 | c.2958G>A p.A986= (on ENST00000404938 / NM_001163941.2; = p.A541= on NM_178559.6) | Silent (SNP) | VAF 32/100 reads (32%) | catalogued as rs773480139, COSV51706119; called by muse, mutect2, varscan2
- ABLIM3 | c.528C>T p.F176= | Silent (SNP) | VAF 74/163 reads (45%) | called by muse, mutect2, varscan2
- ADAMTS14 | c.315C>T p.S105= | Silent (SNP) | VAF 147/393 reads (37%) | catalogued as COSV100941787; called by muse, mutect2, varscan2
- CAD | c.6399G>A p.E2133= | Silent (SNP) | VAF 73/265 reads (28%) | called by muse, mutect2, varscan2
- CNTN6 | c.2923A>C p.R975= | Silent (SNP) | VAF 37/39 reads (95%) | catalogued as rs755233831, COSV100610613, COSV63189798; called by muse, mutect2, varscan2
- CSMD1 | c.5379C>T p.N1793= (on ENST00000520002; = p.N1792= on NM_033225.6) | Silent (SNP) | VAF 161/235 reads (69%) | catalogued as rs769926696; called by muse, mutect2, varscan2
- CTSG | c.414C>T p.P138= | Silent (SNP) | VAF 18/178 reads (10%) | called by muse, mutect2
- CYP2D6 | c.120G>T p.L40= | Silent (SNP) | VAF 156/503 reads (31%) | called by muse, mutect2, varscan2
- FANCM | c.3468C>T p.S1156= | Silent (SNP) | VAF 9/127 reads (7%) | called by muse, mutect2
- FLNB | c.4290G>T p.G1430= | Silent (SNP) | VAF 96/205 reads (47%) | called by muse, mutect2, varscan2
- GPCPD1 | c.537C>G p.L179= | Silent (SNP) | VAF 193/400 reads (48%) | catalogued as COSV66830428; called by muse, mutect2, varscan2
- HTR3D | c.1005C>T p.T335= (on ENST00000382489 / NM_001163646.2; = p.T160= on NM_182537.3) | Silent (SNP) | VAF 163/762 reads (21%) | called by muse, mutect2, varscan2
- IRF7 | c.192C>T p.D64= (on ENST00000397566; = p.D51= on NM_001572.5) | Silent (SNP) | VAF 188/309 reads (61%) | called by muse, mutect2, varscan2
- JSRP1 | c.633C>T p.D211= | Silent (SNP) | VAF 136/297 reads (46%) | catalogued as COSV55554028; called by muse, mutect2, varscan2
- KIF16B | c.2073G>A p.E691= | Silent (SNP) | VAF 83/316 reads (26%) | called by muse, mutect2, varscan2
- MAP1B | c.1386G>A p.P462= | Silent (SNP) | VAF 80/165 reads (48%) | catalogued as rs368021857; called by muse, mutect2, varscan2
- MSL2 | c.276A>G p.E92= | Silent (SNP) | VAF 90/454 reads (20%) | called by muse, mutect2, varscan2
- NASP | c.813G>A p.E271= | Silent (SNP) | VAF 98/192 reads (51%) | called by muse, mutect2, varscan2
- OPCML | c.987T>G p.A329= | Silent (SNP) | VAF 112/211 reads (53%) | catalogued as rs1424119894, COSV59409651, COSV59428469; called by muse, mutect2, varscan2
- PPEF2 | c.1230C>T p.T410= | Silent (SNP) | VAF 128/201 reads (64%) | catalogued as rs754840987, COSV54421172; called by muse, mutect2, varscan2
- PRDM12 | c.507C>T p.N169= | Silent (SNP) | VAF 71/277 reads (26%) | catalogued as rs369430134; called by muse, varscan2
- PRDM9 | c.12A>G p.E4= | Silent (SNP) | VAF 121/424 reads (29%) | called by muse, mutect2, varscan2
- RDH13 | c.780G>A p.L260= (on ENST00000415061 / NM_001145971.2; = p.L189= on NM_138412.4) | Silent (SNP) | VAF 26/86 reads (30%) | catalogued as rs1282023012; called by muse, mutect2, varscan2
- RNF217 | c.522C>T p.P174= | Silent (SNP) | VAF 74/163 reads (45%) | catalogued as rs752110814; called by muse, mutect2, varscan2
- SIX3 | c.555C>T p.L185= | Silent (SNP) | VAF 101/383 reads (26%) | catalogued as rs767766940; called by muse, mutect2, varscan2
- SOX3 | c.1014C>T p.P338= | Silent (SNP) | VAF 31/65 reads (48%) | called by muse, mutect2, varscan2
- STAB2 | c.2625T>C p.T875= | Silent (SNP) | VAF 34/147 reads (23%) | called by muse, mutect2, varscan2
- SULT6B1 | c.576T>C p.H192= (on ENST00000535679 / NM_001367551.1; = p.H154= on NM_001032377.2) | Silent (SNP) | VAF 6/55 reads (11%) | called by muse, mutect2, varscan2
- TRAV26-2 | c.165G>A p.Q55= | Silent (SNP) | VAF 73/229 reads (32%) | catalogued as rs1198540441; called by muse, mutect2, varscan2
- TSG101 | c.12G>A p.S4= | Silent (SNP) | VAF 135/219 reads (62%) | called by muse, mutect2, varscan2
- ULK1 | c.2118G>A p.A706= | Silent (SNP) | VAF 40/203 reads (20%) | catalogued as rs768265590; called by muse, mutect2
- ZAR1 | c.699G>A p.A233= | Silent (SNP) | VAF 92/127 reads (72%) | catalogued as rs1262970999; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73846185 G>C | 5'Flank (SNP) | VAF 215/216 reads (100%) | called by muse, mutect2, varscan2
- ARRDC3 | c.*14T>C | 3'UTR (SNP) | VAF 36/83 reads (43%) | called by muse, mutect2, varscan2
- CALY | c.361-189G>A | Intron (SNP) | VAF 43/105 reads (41%) | called by muse, mutect2, varscan2
- CMTM3 | c.400-87G>T | Intron (SNP) | VAF 86/199 reads (43%) | catalogued as COSV100411870; called by muse, mutect2, varscan2
- ETHE1 | c.*15G>T | 3'UTR (SNP) | VAF 271/420 reads (65%) | called by muse, mutect2, varscan2
- FOXP3 | c.1146+40A>G | Intron (SNP) | VAF 77/203 reads (38%) | called by muse, mutect2, varscan2
- KRT7 | chr12:52253746 G>A | 3'Flank (SNP) | VAF 80/251 reads (32%) | catalogued as rs776317807; called by muse, mutect2, varscan2
- MTR | c.-199C>T | 5'UTR (SNP) | VAF 75/302 reads (25%) | called by muse, mutect2, varscan2
- PKD2L2 | chr5:137889445 C>T | 5'Flank (SNP) | VAF 76/277 reads (27%) | catalogued as COSV51798982; called by muse, mutect2, varscan2
- PRDM11 | chr11:45227093 G>A | 3'Flank (SNP) | VAF 232/369 reads (63%) | catalogued as rs780830634; called by muse, mutect2, varscan2
- PRORY | n.511C>A | RNA (SNP) | VAF 13/93 reads (14%) | called by muse, mutect2, varscan2
- RNF220 | c.907-145G>A | Intron (SNP) | VAF 78/161 reads (48%) | catalogued as rs761814515; called by muse, mutect2, varscan2
- SPAG16-DT | n.490C>T | RNA (SNP) | VAF 5/31 reads (16%) | catalogued as rs773260437; called by muse, mutect2, varscan2
- ZNF213 | chr16:3146021 C>T | 3'Flank (SNP) | VAF 70/149 reads (47%) | catalogued as rs542118162; called by muse, mutect2, varscan2
